Somatic mutation profile of tumor specimen MP2PRT-PASPDY-TMP1-A (aliquot MP2PRT-PASPDY-TMP1-A-1-0-D-A81N-36) from MP2PRT case MP2PRT-PASPDY, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.9 years (679 days).
Specimen MP2PRT-PASPDY-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f49491f5-6ea2-4afe-95fa-b56f65b2dcb6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASPDY-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASPDY-NB1-A-1-0-D-A81N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9cb3c742-ada9-46cf-806b-50d8f1196b67

The open-access MAF lists 14 somatic variants for this specimen: 10 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 8, Silent 4, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CD | c.3061G>A p.E1021K | Missense Mutation (SNP) | VAF 59/390 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs397518423, CM067447, COSV63126880; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GET1-SH3BGR | c.377C>G p.A126G | Missense Mutation (SNP) | VAF 50/216 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.875); catalogued as COSV61322123; called by muse, varscan2
- GRIK5 | c.1388G>A p.R463H | Missense Mutation (SNP) | VAF 159/588 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.873); catalogued as rs750778626, COSV53475565; called by muse, mutect2, varscan2
- KRT72 | c.937G>A p.E313K | Missense Mutation (SNP) | VAF 74/246 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs755309278, COSV99537102; called by muse, mutect2
- MAGEB10 | c.979C>T p.R327C | Missense Mutation (SNP) | VAF 19/319 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.353); catalogued as rs1323890664, COSV63312543; called by muse, mutect2
- RAD21 | c.1756C>T p.R586* | Nonsense Mutation (SNP) | VAF 73/257 reads (28%) | catalogued as COSV52056480; called by muse, mutect2, varscan2
- CLCN6 | c.1820C>T p.P607L | Missense Mutation (SNP) | VAF 65/378 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.345); called by muse, mutect2, varscan2
- ENPP4 | c.1193del p.D398Afs*21 | Frame Shift Del (DEL) | VAF 93/377 reads (25%) | called by mutect2, pindel, varscan2
- NUTM1 | c.2697A>T p.E899D | Missense Mutation (SNP) | VAF 105/448 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.005); called by muse, varscan2
- NUTM1 | c.2826G>T p.K942N | Missense Mutation (SNP) | VAF 123/314 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.087); called by muse, varscan2
- ANKRD50 | c.3195A>G p.L1065= | Silent (SNP) | VAF 20/358 reads (6%) | called by muse, mutect2
- NOTCH1 | c.6321C>T p.H2107= | Silent (SNP) | VAF 191/855 reads (22%) | catalogued as rs532201830, COSV53032779; ClinVar: likely benign; called by muse, mutect2, varscan2
- OR8J3 | c.723C>T p.C241= | Silent (SNP) | VAF 51/180 reads (28%) | catalogued as rs760857965, COSV56879597, COSV56884655; called by muse, mutect2, varscan2
- SLC12A1 | c.426G>A p.V142= | Silent (SNP) | VAF 12/207 reads (6%) | called by muse, mutect2
